Gene-level copy-number profile of tumor specimen HCM-SANG-0535-C20-08A-01D-A80T-32 from HCMI case HCM-SANG-0535-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0535-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb38cfff-4148-46e1-8782-ccde5de21b1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0535-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/25304831-5bb9-4aa0-ac11-0a9117da4239

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 1,983; copy number 2: 36,236; copy number 3: 12,248; copy number 4: 7,417; copy number 5: 452; copy number 6: 66.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 518 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,831,942–51,225,575, 116 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr2:51,011,777–51,016,950, 1 gene, copy number 5: AC007682.1.
- chr13:20,403,666–41,385,183, 379 genes, copy number 5–6 (broad region; genes not listed).
- chr13:44,575,893–44,809,630, 5 genes, copy number 6 (within-gene range 4–6): TSC22D1-AS1, SMARCE1P5, LINC00407, AL356515.1, LINC00330.
- chr16:14,708,944–14,726,338, 1 gene, copy number 5: NPIPA3.
- chr16:14,748,066–14,953,120, 16 genes, copy number 5 (within-gene range 3–5): NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3.

Autosomal genes at a single copy (total copy number 1): 1,983. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
